TARGET case TARGET-51-PALLXV — Clear Cell Sarcoma of the Kidney (TARGET-CCSK)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/702290ef-d941-5f40-aaa5-705477c9236d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 1 years; Vital status: Dead; Days to death: 2,188 days (6.0 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Clear cell sarcoma of kidney: ICD-O-3 morphology code: 8964/3; ICD-10 code: C64; Tissue or organ of origin: Kidney, NOS; Classification of tumor: primary; Age at diagnosis: 1.3 years (463 days); Year of diagnosis: 2002; Days to last follow up: 2,188 days (6.0 years); Pediatric kidney staging: Nephrectomy specimen with tumor that is present at the surgical margin of resection or within regional lymph nodes, no distant metastasis.
   Treatment given: Protocol identifier: NWTS-5.

Follow-up (2 entries)
- Days to follow up: 468 days (1.3 years); Days to first event: 468 days (1.3 years); First event: Relapse.
- Days to follow up: 2,188 days (6.0 years); Year of follow up: 2008.

Biospecimens (2 samples)
- Sample TARGET-51-PALLXV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-51-PALLXV-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_CCSK_ClinicalData_Discovery_20230322.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 2188
- Stage: III
- ICD-O-3-T: C649
- Histologic Classification of Primary Tumor: CCSK

Additional fields from the TARGET clinical supplement workbook TARGET_CCSK_ClinicalData_Discovery_Percent_Tumor_Nuclei_and_Necrosis_Supplement_20230322.xlsx (sheet CCSK Data), for sample TARGET-51-PALLXV-01A-01:
- Histological Subtype: CCSK
- Specimen Type: frozen solid tumor
- Pathology: Diagnosis Confirmed: yes
- % Tumor Nuclei: Top: 85
- % Non tumor Nuclei: Top: 15
- % Cellular Tumor: Top: 100
- % Normal: Top: 0
- % Stroma: Top: 0
- % Necrosis: Top: 0
- % Tumor Nuclei: Bottom: 85
- % Non tumor Nuclei: Bottom: 15
- % Cellular Tumor: Bottom: 100
- % Normal: Bottom: 0
- % Stroma: Bottom: 0
- % Necrosis: Bottom: 0
- Pathology Pass/Fail: pass

Additional fields from the TARGET clinical supplement workbook TARGET_CCSK_ClinicalData_Discovery_Percent_Tumor_Nuclei_and_Necrosis_Supplement_20230322.xlsx (sheet CCSK Data), for sample TARGET-51-PALLXV-11A-01:
- Histological Subtype: CCSK
- Specimen Type: normal solid tissue
- Pathology: Diagnosis Confirmed: yes
- % Cellular Tumor: Top: 0
- % Normal: Top: 100
- % Stroma: Top: 0
- % Necrosis: Top: 0
- % Cellular Tumor: Bottom: 0
- % Normal: Bottom: 100
- % Stroma: Bottom: 0
- % Necrosis: Bottom: 0
- Pathology Pass/Fail: pass
